Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A7M7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A7M7-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected
Time Reported
Order Number
Status

Final

Time Received
Time Transmitted
Ordering Provider
Relevant Information
Location

Copied To

Report Patient
Demographics (for
verification purposes)

Date of Birth
Sex:

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description
A. Gallbladder
B. Liver segment 5-8

Clinical Information
Hepatocellular carcinoma. Positive margin ablated.
Infectious patient: No
Immunocompromised: No
History of neoplasm: No

Diagnosis

A. Gallbladder, Resection:
No malignancy.

B. Liver, Partial Hepatectomy:
- Hepatocellular carcinoma (see synoptic report)
- Chronic hepatitis with severe steatosis (60%) consistent with
alcoholic hepatitis, fibrosis stage III

Reported by:

Electronically signed by:
Verified:

Responsible Resident

Synoptic Report

Specimen:
Liver

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
9/25/13

[page 2 of 2]
PROCEDURE:

Partial hepatectomy

TUMOR SIZE:

Greatest dimension: 3.7 cm

*Additional dimensions: 3.5 cm x 3.1 cm

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GI: Well differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.1 mm

Bile duct margin cannot be assessed

Other margin cannot be assessed

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Hepatitis (specify type): Alcoholic hepatitis

Gross Description

Received are specimen containers A to B. All requisitions and specimen containers are
labelled with the patient's name, The cassettes and are
labelled with the Surgical Number

A. Specimen is received fresh and designated "gallbladder". The specimen consists of an intact gallbladder weighing 71.3 g and measuring 10.6 x 4.5 x 3.3 cm. The serosa is smooth and there is attached adipose tissue. The lumen contains semiliquid, green, mucus material. No stones are identified. The gallbladder wall measures 0.1 cm in thickness and is unremarkable. The mucosal surface is unremarkable. The cystic duct is patent. No lymph nodes are identified. Representative sections are submitted in cassette A1.

B. Specimen is received fresh and designated "liver segment". The specimen consists of a segment of liver tissue measuring 8.5 x 8.5 x 4.5 cm and weighing 128.4 g in the fixed state. The resection margin is painted blue. The capsule is smooth but appears to be congested with focal yellow, round discoloration. Adjacent to the resection, there is a yellow, firm nodule measuring 3.7 x 3.5 x 3.1 cm. The tumor is 0.4 cm to the closest capsule. The remaining liver parenchyma appears fatty. Representative sections are submitted as follows:

B1 through B4 - tumor with closest resection margin.

B5 - tumor with closest capsule.

B6 - liver parenchyma adjacent to the tumor.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 85425e95-0373-4ce0-804c-b056328b8f06 (TCGA-G3-A7M7.9EC72408-F4C7-4D95-ACE3-3BF44E10FF8C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).